Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AAET, project TCGA-TGCT (Testicular Germ Cell Tumors), specimen TCGA-2G-AAET-01A (Primary Tumor).

Department of Pathology

ICD O-3
Seminoma NOS 9061.3
Site R Testis NOS C62.9
7/3/14

Direct dial

Mobile:

Internal postal address

E-mail

Date

Concerning

Summary pathology report

Right orchidectomy; seminoma; diameter 5 cm; no invasion of rete testis; angio-invasion present; no invasion of tunica albuginea; epididymis free of tumor; tumor present in vessels of spermatic cord; surgical margin of spermatic cord free of tumor.

Date of procurement (= date of orchidectomy):

pathologist

professor of pathology

Source: NCI Genomic Data Commons file bcb0fc46-dd4c-4ca1-9696-34a3cade8993 (TCGA-2G-AAET-01A.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).